TCGA case TCGA-FF-A7CX — Lymphoid Neoplasm Diffuse Large B-cell Lymphoma (TCGA-DLBC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mature B-Cell Lymphomas; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: SingHealth. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/29e3d122-15a1-4235-a356-b1a9f94ceb39

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Singapore; Age at index: 46 years; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; ICD-10 code: C49.0; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of head, face, and neck; Classification of tumor: primary; Age at diagnosis: 46.3 years (16,924 days); Year of diagnosis: 2011; AJCC staging edition: 7th; Ann Arbor clinical stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 385 days (1.1 years); Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Lung; Sites of involvement: Lymph Node, Cervical / Adrenal gland, NOS / Soft tissue / Brain, NOS / Thyroid / Lung, NOS.
   Pathology details: Additional pathology findings: Percent follicular component <= 10%.
   Pathology details: Bone marrow malignant cells: No; Consistent pathology review: Yes; Greatest tumor dimension: 2.4 cm; Measurement unit: Centimeters.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CHOP; Days to treatment start: 10 days; Days to treatment end: 140 days; Number of cycles: 7.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Methotrexate; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CHOP; Days to treatment start: 10 days; Days to treatment end: 140 days; Number of cycles: 6.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CHOP; Days to treatment start: 10 days; Days to treatment end: 140 days; Number of cycles: 7.
   Recorded as not given: adjuvant Radiation Therapy, NOS; Stem Cell Transplantation, NOS.

Follow-up (3 entries)
- Days to follow up: 385 days (1.1 years); Disease response: Tumor Free.
- ECOG performance status: 0.
- Follow-up contact recording only the day: within 2 months after completion of first-course treatment.

Molecular and laboratory tests
- BCL10 (FISH): Normal.
- BCL2 (FISH): Normal.
- BCL2 (IHC): Positive.
- BCL6 (FISH): Normal.
- BCL6 (IHC): Positive.
- CCND1 (FISH): Normal.
- CCND1 (IHC): Negative.
- CD10 (IHC): Negative.
- CD20 (IHC): Positive.
- CD5 (IHC): Negative.
- IGH (FISH): Normal.
- IRF4 (IHC): Positive.
- Immunoglobulin, Cytoplasmic (IHC): Positive.
- MALT1 (FISH): Normal.
- MYC (FISH): Normal.
- PAX5 (FISH): Normal.
- Epstein-Barr Virus (IHC): Negative.
- Lactate Dehydrogenase 714 IU [Blood test normal range upper: 380].
- Involved Tissue, NOS epstein-barr virus (ISH): Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 66 kg; Height: 174 cm; BMI: 21.8.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FF-A7CX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 160 mg.
  Slide TCGA-FF-A7CX-01A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 85; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 5.
- Sample TCGA-FF-A7CX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Primary pathology: Follicular component percent: < or = 10%; Extranodal site involvement: 4; Bone marrow biopsy performed: Yes.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Adrenal; Submitted tumor site: Soft Tissue (muscle  ligaments  subcutaneous); Submitted tumor site: Brain; Submitted tumor site: Thyroid.
- Tests performed: LDH level: 714; Mib 1 positive percent range: 51 - 75%; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunopheotypic analysis tested: CD10 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunopheotypic analysis tested: BCL2; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunopheotypic analysis tested: CD20; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunopheotypic analysis tested: MUM1 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunopheotypic analysis tested: BCL6 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunopheotypic analysis tested: CD5; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunopheotypic analysis tested: Cytoplasmic Ig; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunopheotypic analysis tested: Eber; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 9: Immunopheotypic analysis tested: Cyclin D1; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc; Genetic abnormality tested other: PAX 5.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality tested: BCL2; Genetic abnormality tested other: IGH.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 3: Genetic abnormality tested: BCL6; Genetic abnormality tested other: BCL10.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 4: Genetic abnormality tested: CCND1.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 5: Genetic abnormality tested: MALT1.
- New tumor event: Pet scan after treatment results: Not Done; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form: Lost to follow-up: Yes; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Drug treatment 1: Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: R-CHOP, IT-MTX.
- Drug treatment 2: Pharmaceutical therapy drug name: Hydroxydaunomycin; Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: R-CHOP, IT-MTX.
- Drug treatment 3: Pharmaceutical therapy drug name: Prednisolone; Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: R-CHOP, IT-MTX.
- Drug treatment 5: Pharmaceutical therapy drug name: Oncovin; Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: R-CHOP, IT-MTX.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 385 days; disease-specific survival: no event (censored), 385 days; progression-free interval: no event (censored), 385 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FF-A7CX-01A-12D-A381-01): tumor purity 0.92, ploidy 1.96, whole-genome doublings 0.
